Surgical pathology report (de-identified scan), TCGA case TCGA-TM-A84Q, project TCGA-LGG (Brain Lower Grade Glioma), tissue source site The University of New South Wales, specimen TCGA-TM-A84Q-01A (Primary Tumor).

[page 1 of 2]
Collected:

Ordered by:

CLINICAL DETAILS

(L) temporal tumour for frozen section. Headaches

speech disturbance.

FROZEN SECTION REPORT

1. Examined by frozen section and reported by

"Glioma".

MACROSCOPIC DESCRIPTION

1. LABELLED 'LEFT TEMPORAL TUMOUR'. An aggregate of red tissue 25 x 10 x 2mm sampled for smears and frozen section. Block 1A frozen section, 1B remainder of tissue.

2. LABELLED 'LEFT TEMPORAL TUMOUR'. Multiple fragments of friable tan and yellow soft tissue 80 x 80 x 10mm in aggregate. Representative sections embedded in three blocks.

3. LABELLED 'LEFT TEMPORAL TUMOUR'. Multiple fragments of firm tan haemorrhagic tissue 25 x 25 x 10mm in aggregate. The largest pieces have firm tan tissue on sectioning. Representative section embedded in one block.

MICROSCOPIC REPORT

1-3. The processed paraffin sections confirm the frozen section diagnosis. The sections show brain tissue in which there is a gemistocytic astrocytoma. The tumour is predominantly (60-70%) composed of neoplastic gemistocytes with plump, glassy and eosinophilic cells bodies of angular shape. A small amount of grade 2 fibrillary astrocytoma component is also present in the background. No mitoses, necrosis or endothelial proliferation is seen. Adjacent non-neoplastic brain shows prominent perivascular lymphocytic cuffing.

The tumour cells are strongly positive for GFAP. The Ki67 proliferation index is approximately 2%.

Immunohistochemical study for p53 and Bcl2 is in progress. A supplementary report will follow.

COMMENT

Gemistocytic astrocytomas frequently are clinically aggressive and they have a poorer prognosis than is suggested by their histological grade.

This case has been reviewed in consultation with

who agrees with the interpretation.

SUMMARY

Brain, left temporal tumour - Gemistocytic astrocytoma, WHO grade 2.

1CD-0-3

REPORTED BY:

CQCF: Astrocytoma, grade II 9400/3

Path: Astrocytoma, gemistocytic 9411/3

Site Brain, supratentorial NOS C71.2

Brain, temporal lobe C71.2

9/10/30/13

[page 2 of 2]
Case:

SUPPLEMENTARY REPORT

Immunohistochemical study shows the tumour cells are strongly positive for p53. There is patchy weak staining for Bcl2. The immunoprofile is consistent with gemistocytic astrocytoma.

SUPPLEMENTARY SUMMARY

Brain, left temporal tumour - Gemistocytic astrocytoma, WHO grade 2.

REPORTED BY:

Source: NCI Genomic Data Commons file 852d27fc-7929-4520-9dc3-9c9cdff7b3e0 (TCGA-TM-A84Q.CE780D35-9DBE-4596-812C-D44B2B57466D.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).